Gene-level copy-number profile of tumor specimen TCGA-08-0358-01A from TCGA case TCGA-08-0358, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.3 years (18,383 days).
Specimen TCGA-08-0358-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.9667bd6f-eae5-4eb7-b7eb-84b94a735233.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-08-0358-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 391 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8d53dc22-8e48-492b-9e9a-c52a044536ad

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 7,374; copy number 2: 552; copy number 3: 49,116; copy number 4: 101; copy number 5: 1,109; copy number 7: 1,875; copy number 8: 14; copy number 9: 1; copy number 12: 1; copy number 53: 4; copy number 58: 14; copy number 66: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-08-0358-01): tumor purity 0.95, ploidy 1.97, whole-genome doublings 0 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,160,235–24,088,051, 65 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,912 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:16,461,481–21,028,813, 65 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr7:47,275,154–94,077,157, 814 genes, copy number 7–66 (within-gene range 5–66) (broad region; genes not listed).
- chr7:105,439,661–159,233,377, 1,033 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,005. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
